Somatic mutation profile of tumor specimen TCGA-JV-A5VE-01A (aliquot TCGA-JV-A5VE-01A-11D-A29N-09) from TCGA case TCGA-JV-A5VE, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 60.0 years (21,933 days).
Specimen TCGA-JV-A5VE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5510bc20-7b27-4586-8f44-198bc464256d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JV-A5VE-10A (Blood Derived Normal), aliquot TCGA-JV-A5VE-10A-01D-A29N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c60bffc-ae80-4551-aa81-b732fd53aaad

The open-access MAF lists 46 somatic variants for this specimen: 38 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 6, Nonsense Mutation 2, Frame Shift Ins 1, 5'Flank 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.4351C>A p.P1451T (on ENST00000303395 / NM_001202435.3; = p.P1440T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs794726696, CM113335, CM1511241, COSV100320969, COSV100322186; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.3075T>A p.F1025L | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV100750909; called by muse, mutect2, varscan2
- AHNAK | c.5845G>C p.G1949R | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV99948166; called by muse, mutect2, varscan2
- AHNAK2 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.208); catalogued as COSV100318059; called by muse, mutect2, varscan2
- ANKRD50 | c.790A>T p.K264* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV101538992; called by muse, mutect2, varscan2
- ATRX | c.6440G>T p.S2147I | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1569523183, COSV100971064; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C3AR1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.5); catalogued as rs745382932, COSV50817584; called by muse, mutect2, varscan2
- CCDC85B | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.685); catalogued as COSV100440937; called by muse, mutect2, varscan2
- CNKSR2 | c.2779C>A p.H927N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV101072806; called by muse, mutect2
- CNOT1 | c.4777G>C p.G1593R | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.5); PolyPhen benign (0.214); catalogued as COSV99800541; called by muse, mutect2, varscan2
- COPS4 | c.890C>G p.S297C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV100018684; called by muse, mutect2, varscan2
- ELL3 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.711); catalogued as rs767146967, COSV100082616; called by muse, mutect2, varscan2
- FAM122B | c.366G>T p.R122S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV99980384; called by muse, varscan2
- FAM122B | c.365G>C p.R122T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99980388; called by muse, mutect2, varscan2
- KAT6A | c.5720C>T p.P1907L | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV99705391; called by muse, mutect2
- NEMF | c.1208C>G p.T403R | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV100027748; called by muse, mutect2, varscan2
- NHSL2 | c.955A>T p.T319S (on ENST00000510661; = p.T685S on NM_001013627.2) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101030190; called by muse, mutect2, varscan2
- OR1G1 | c.666C>G p.F222L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV100187564, COSV61030692; called by muse, mutect2, varscan2
- OR8D1 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100766662; called by muse, mutect2, varscan2
- P4HA2 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs753260673, COSV99387136; called by muse, mutect2, varscan2
- PHKA2 | c.3282+1del p.X1094_splice | Splice Site (DEL) | VAF 37/81 reads (46%) | catalogued as COSV66052181; called by mutect2, pindel, varscan2
- PLA2G12B | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.77); PolyPhen benign (0.072); catalogued as rs372066733; called by muse, mutect2, varscan2
- PROM1 | c.1796A>T p.E599V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV101477099, COSV71700171; called by muse, mutect2, varscan2
- PROSER1 | c.517A>C p.N173H | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV100612864; called by muse, mutect2
- QRFPR | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV100543817; called by muse, mutect2, varscan2
- RELN | c.2898A>T p.E966D | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.47); PolyPhen benign (0.079); catalogued as rs1451855871, COSV100634087; called by muse, mutect2, varscan2
- ROBO3 | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as rs372770487; called by muse, mutect2, varscan2
- SCML1 | c.242T>G p.V81G (on ENST00000380041 / NM_001037540.3; = p.V54G on NM_006746.6) | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV101193954; called by muse, mutect2
- SIL1 | c.1235A>G p.Y412C | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV99498238; called by muse, mutect2, varscan2
- SLC6A17 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV58991891; called by muse, mutect2, varscan2
- SMC3 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.62); PolyPhen benign (0.038); catalogued as COSV100699950; called by muse, mutect2, varscan2
- SNTG1 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1330414533, COSV52478194, COSV99384461; called by muse, mutect2, varscan2
- STON1 | c.2195G>T p.C732F | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100561984; called by muse, mutect2, varscan2
- TEX30 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs767857286, COSV65697591; called by muse, mutect2
- TIMELESS | c.362A>G p.K121R | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1014868721, COSV99974098; called by muse, mutect2, varscan2
- TRIOBP | c.4828G>A p.G1610R | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100730945; called by muse, mutect2, varscan2
- ZBTB3 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV101188982; called by muse, mutect2, varscan2
- VPS13B | c.128dup p.L44Vfs*21 | Frame Shift Ins (INS) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- ASTL | c.147C>A p.A49= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as rs765956869, COSV100668389, COSV60903787; called by muse, mutect2, varscan2
- FAM9B | c.345C>T p.D115= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs150312431, COSV59120612; called by muse, mutect2, varscan2
- FOLR3 | c.621C>T p.G207= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV100281809; called by muse, mutect2, varscan2
- KIF21A | c.1074G>T p.T358= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs749287416, COSV100735517; called by muse, varscan2
- SMARCA2 | c.3021C>T p.N1007= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs886041042, COSV100571296; called by muse, mutect2, varscan2
- WNT5B | c.855C>T p.P285= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs761730416, COSV100148741; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502696 G>T | 5'Flank (SNP) | VAF 8/33 reads (24%) | catalogued as rs1267890508; called by muse, mutect2, varscan2
- CCDC159 | c.22-593A>G | Intron (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
